Somatic mutation profile of tumor specimen C3L-07081-03 (aliquot CPT0411980006) from CPTAC case C3L-07081, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 68.3 years (24,954 days).
Specimen C3L-07081-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b35404a1-20e7-4a5c-8f3f-69d8e36f0971.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07081-31 (Blood Derived Normal), aliquot CPT0412140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75fd174c-986f-40d1-be6d-66e87388e1be

The open-access MAF lists 1,774 somatic variants for this specimen: 1,312 protein-altering or splice-affecting, 386 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 944, Silent 386, Frame Shift Del 259, Intron 45, Frame Shift Ins 44, Nonsense Mutation 36, In Frame Del 12, 3'UTR 10, 3'Flank 9, Splice Site 7, Splice Region 6, 5'UTR 4.

Variants (750 of 1,774; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG6 | c.634dup p.C212Lfs*9 | Frame Shift Ins (INS) | VAF 32/262 reads (12%) | catalogued as rs879133727; ClinVar: likely pathogenic; called by mutect2, varscan2
- C19orf12 | c.199del p.A67Lfs*6 (on ENST00000392278 / NM_001031726.3; = p.A56Lfs*6 on NM_031448.6) | Frame Shift Del (DEL) | VAF 24/188 reads (13%) | catalogued as rs398122409, CD129885, CD132613; ClinVar: pathogenic; called by mutect2, pindel
- CHD8 | c.2626C>T p.R876* (on ENST00000646647 / NM_001170629.2; = p.R597* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 47/362 reads (13%) | catalogued as rs1555315679, COSV101303044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL1A1 | c.1127del p.P376Lfs*165 | Frame Shift Del (DEL) | VAF 56/414 reads (14%) | catalogued as rs72645369, CD961894; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DGKE | c.610del p.T204Qfs*6 | Frame Shift Del (DEL) | VAF 15/139 reads (11%) | catalogued as rs147972030; ClinVar: pathogenic; called by mutect2, pindel
- EP300 | c.4016T>C p.M1339T | Missense Mutation (SNP) | VAF 27/273 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1064795607; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 40/302 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1057519803, COSV57246350, COSV57249681; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LMNA | c.1824C>T p.G608= | Silent (SNP) | VAF 56/600 reads (9%) | catalogued as rs58596362, CS032429; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 52/312 reads (17%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NEK9 | c.1718T>C p.I573T | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.628); catalogued as rs1555352529, COSV53132044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OPLAH | c.2608del p.H870Tfs*28 | Frame Shift Del (DEL) | VAF 57/542 reads (11%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PEX1 | c.1108del p.I370Lfs*17 | Frame Shift Del (DEL) | VAF 60/347 reads (17%) | catalogued as rs61750406; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 32/320 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PKD1 | c.8427del p.E2810Rfs*65 | Frame Shift Del (DEL) | VAF 55/499 reads (11%) | catalogued as rs1567177760; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RIMS1 | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs121918302, CM034832; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- RTEL1 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 62/395 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205700, CM154440; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TBCD | c.3125C>T p.P1042L | Missense Mutation (SNP) | VAF 55/396 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs760635077; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/228 reads (15%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- AARS2 | c.2067dup p.Q690Afs*3 | Frame Shift Ins (INS) | VAF 69/452 reads (15%) | catalogued as rs1342070328; called by mutect2, pindel, varscan2
- AARS2 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 44/346 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs898375030; called by muse, mutect2, varscan2
- ABLIM2 | c.1576C>T p.R526W (on ENST00000341937 / NM_001130084.2; = p.R560W on NM_001130083.2) | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); catalogued as rs556466250; called by muse, mutect2, varscan2
- AC068580.4 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.163); catalogued as rs777645484, COSV52589637; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ACE | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 56/446 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs989791368, COSV52007304; called by muse, mutect2, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 52/421 reads (12%) | catalogued as rs879396950, COSV52972585; called by mutect2, pindel, varscan2
- ACP7 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs1352763634, COSV58698443; called by muse, mutect2, varscan2
- ACSL6 | c.1445C>T p.A482V (on ENST00000379240; = p.A507V on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.2); catalogued as rs575021630; called by muse, mutect2
- ADAMTS5 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 71/492 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV99537105; called by muse, varscan2
- ADAMTSL3 | c.3959G>A p.R1320Q | Missense Mutation (SNP) | VAF 25/288 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs780927968; called by muse, mutect2
- ADD3 | c.1590_1592del p.V531del | In Frame Del (DEL) | VAF 34/294 reads (12%) | catalogued as rs1334386005; called by pindel, varscan2
- ADGRB2 | c.1183del p.Q395Sfs*29 | Frame Shift Del (DEL) | VAF 66/472 reads (14%) | catalogued as rs766087842; called by mutect2, pindel, varscan2
- ADGRL2 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 47/446 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1325228176, COSV54658549; called by muse, mutect2, varscan2
- ADGRV1 | c.15818C>A p.A5273E | Missense Mutation (SNP) | VAF 45/418 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV67980379; called by muse, mutect2, varscan2
- ADRA1B | c.1301G>A p.G434D | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.023); catalogued as rs1220633115; called by muse, mutect2, varscan2
- AFDN | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 44/357 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369982894; called by muse, mutect2, varscan2
- AGAP4 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 45/492 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1347036003; called by muse, mutect2, varscan2
- AGL | c.4459C>T p.R1487* | Nonsense Mutation (SNP) | VAF 35/308 reads (11%) | catalogued as rs12118058; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- AGPAT4 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs370036938; called by muse, mutect2, varscan2
- AHNAK2 | c.6331G>A p.D2111N | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs192885667, COSV60915218; called by muse, mutect2, varscan2
- AIFM3 | c.734A>C p.Q245P | Missense Mutation (SNP) | VAF 48/338 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV58997390; called by muse, mutect2, varscan2
- AKAP17A | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 34/868 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1184082441; called by muse, mutect2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 42/310 reads (14%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 50/412 reads (12%) | catalogued as COSV62339755; called by mutect2, varscan2
- ALDH1A3 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1164081840; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 35/286 reads (12%) | catalogued as rs771889973, COSV55672572; called by mutect2, pindel, varscan2
- ALDH3B1 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs369465283; called by muse, mutect2, varscan2
- ANAPC2 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs767471831; called by muse, mutect2
- ANK1 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs1221815487; called by muse, mutect2, varscan2
- ANKRD11 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 62/412 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs771852521; called by muse, mutect2, varscan2
- ANKRD13B | c.1184T>C p.V395A | Missense Mutation (SNP) | VAF 58/356 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV61470371; called by muse, mutect2, varscan2
- ANKRD2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 81/573 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs780964391; called by muse, mutect2, varscan2
- ANKRD31 | c.2778del p.K926Nfs*9 | Frame Shift Del (DEL) | VAF 39/255 reads (15%) | catalogued as COSV57158864; called by mutect2, pindel, varscan2
- AOPEP | c.1036T>C p.W346R | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758414518; called by muse, varscan2
- AOPEP | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 44/317 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs960335746; called by muse, mutect2, varscan2
- AP2A1 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 66/339 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1010858993; called by muse, mutect2, varscan2
- AP3D1 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531735484; called by muse, varscan2
- AP4B1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs968023503; called by muse, mutect2, varscan2
- APC2 | c.2312A>G p.Y771C | Missense Mutation (SNP) | VAF 70/542 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1568177789; called by muse, mutect2, varscan2
- ARHGAP45 | c.2056G>A p.V686M | Missense Mutation (SNP) | VAF 53/372 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs370399922; called by muse, mutect2, varscan2
- ARHGEF12 | c.4012C>T p.R1338W | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.226); catalogued as rs200873841; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 64/445 reads (14%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID1A | c.6146G>A p.W2049* | Nonsense Mutation (SNP) | VAF 47/443 reads (11%) | catalogued as COSV61372385; called by muse, mutect2, varscan2
- ARID1B | c.1243del p.A415Pfs*15 | Frame Shift Del (DEL) | VAF 30/268 reads (11%) | catalogued as rs1417035592; called by mutect2, pindel, varscan2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 52/393 reads (13%) | catalogued as rs965020534; called by mutect2, varscan2
- ASCC2 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs748143807, COSV100316195, COSV57075264; called by muse, mutect2
- ASH1L | c.7582C>T p.R2528C (on ENST00000368346 / NM_001366177.2; = p.R2523C on NM_018489.3) | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as rs1376913986, COSV64208707; called by muse, mutect2, varscan2
- ATG2A | c.4244C>T p.P1415L | Missense Mutation (SNP) | VAF 57/426 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764367652; called by muse, mutect2, varscan2
- ATG2B | c.6196C>T p.R2066W | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761750367, COSV99951992; called by muse, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 84/355 reads (24%) | catalogued as rs771531141; called by mutect2, varscan2
- ATN1 | c.2978C>T p.P993L | Missense Mutation (SNP) | VAF 50/423 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as rs1555144301; called by muse, mutect2, varscan2
- ATP13A3 | c.3341del p.L1114Yfs*22 | Frame Shift Del (DEL) | VAF 22/165 reads (13%) | catalogued as COSV55469110; called by mutect2, pindel, varscan2
- ATP2B2 | c.1730G>A p.R577H (on ENST00000352432; = p.R543H on NM_001683.5) | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774748492; called by muse, mutect2, varscan2
- B3GALT2 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.991); catalogued as rs766787048, COSV66464061; called by muse, mutect2, varscan2
- BAZ1A | c.3266A>G p.Q1089R | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV62411053; called by muse, mutect2, varscan2
- BCL6 | c.1418del p.P473Rfs*117 | Frame Shift Del (DEL) | VAF 54/468 reads (12%) | catalogued as COSV51655892; called by mutect2, pindel, varscan2
- BCL6B | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 38/312 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs773476333, COSV53427873; called by muse, mutect2, varscan2
- BEND2 | c.2249G>A p.C750Y | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748760102; called by muse, mutect2, varscan2
- BEND3 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 62/396 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs781925980; called by muse, mutect2, varscan2
- BHLHE40 | c.1012A>G p.M338V | Missense Mutation (SNP) | VAF 56/472 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.546); catalogued as rs760744157, COSV56574559; called by muse, mutect2, varscan2
- BIN1 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs750715069; called by muse, mutect2, varscan2
- BRSK1 | c.2068G>A p.V690I | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.959); catalogued as rs773668150, COSV58671047; called by muse, mutect2, varscan2
- BTBD16 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 40/399 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV53264804; called by muse, mutect2
- BTNL3 | c.1200del p.S401Afs*7 | Frame Shift Del (DEL) | VAF 44/379 reads (12%) | catalogued as rs757227190; called by mutect2, pindel, varscan2
- C1QL3 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 40/385 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV100127044; called by muse, mutect2, varscan2
- C1orf127 | c.1744G>A p.G582S | Missense Mutation (SNP) | VAF 68/425 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.024); catalogued as rs767739539; called by muse, mutect2, varscan2
- C20orf203 | c.316del p.E106Kfs*73 | Frame Shift Del (DEL) | VAF 45/278 reads (16%) | catalogued as rs1568750079; called by mutect2, pindel, varscan2
- C2orf74 | c.107del p.L36Yfs*25 | Frame Shift Del (DEL) | VAF 26/256 reads (10%) | catalogued as rs1265298443; called by mutect2, pindel, varscan2
- C3 | c.3959G>T p.R1320L | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1426625425, COSV55570849; called by muse, mutect2, varscan2
- C6orf226 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 35/252 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as rs748124881; called by muse, mutect2, varscan2
- C7orf31 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1211201564; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 54/532 reads (10%) | catalogued as rs750339990; called by mutect2, pindel
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 37/307 reads (12%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CA5A | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs1226444061, COSV59240027; called by muse, mutect2, varscan2
- CACNA1E | c.2774G>A p.R925H | Missense Mutation (SNP) | VAF 58/341 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.215); catalogued as rs373971175, COSV62403954; called by muse, mutect2, varscan2
- CACNA1H | c.3317G>T p.G1106V | Missense Mutation (SNP) | VAF 55/413 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV62000090; called by muse, mutect2, varscan2
- CACNG1 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); catalogued as rs376840748; called by muse, mutect2, varscan2
- CAPSL | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs770162293, COSV68437415; called by muse, mutect2, varscan2
- CASKIN1 | c.2747G>A p.R916H | Missense Mutation (SNP) | VAF 69/467 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs969850214, COSV58212889, COSV58213260; called by muse, mutect2, varscan2
- CASP8 | c.698G>A p.R233Q (on ENST00000432109 / NM_033355.3; = p.R250Q on NM_001228.4) | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs771150445, COSV51844924; ClinVar: uncertain significance; called by muse, varscan2
- CASP8 | c.950A>G p.H317R (on ENST00000432109 / NM_033355.3; = p.H334R on NM_001228.4) | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51844767; called by muse, mutect2
- CATSPER3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762834732, COSV50945252, COSV50951948; called by muse, mutect2, varscan2
- CATSPERG | c.2939G>T p.S980I | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99286652; called by muse, mutect2, varscan2
- CAVIN2 | c.50A>G p.D17G | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV58425968; called by muse, mutect2, varscan2
- CCDC115 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as rs762047473, COSV52092798; called by muse, mutect2, varscan2
- CCDC157 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as rs753475863; called by muse, varscan2
- CCDC168 | c.13758del p.E4587Rfs*5 | Frame Shift Del (DEL) | VAF 59/414 reads (14%) | catalogued as rs965061080; called by mutect2, pindel, varscan2
- CCDC88A | c.2032del p.T678Hfs*8 | Frame Shift Del (DEL) | VAF 16/132 reads (12%) | catalogued as COSV55059487; called by mutect2, varscan2
- CCDC88C | c.3676C>T p.R1226W | Missense Mutation (SNP) | VAF 53/437 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs774944606; called by muse, mutect2, varscan2
- CCNH | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1385799292; called by muse, mutect2
- CD27 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761113232; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD70 | c.233del p.G78Afs*33 | Frame Shift Del (DEL) | VAF 46/366 reads (13%) | catalogued as COSV99835502; called by mutect2, pindel, varscan2
- CDH18 | c.1166T>C p.L389P | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56906138; called by muse, mutect2, varscan2
- CDH9 | c.854C>A p.T285N | Missense Mutation (SNP) | VAF 74/421 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs1031798308; called by muse, mutect2, varscan2
- CDKL3 | c.791A>G p.H264R | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.224); catalogued as COSV54741660; called by muse, varscan2
- CELSR1 | c.7346C>T p.A2449V | Missense Mutation (SNP) | VAF 50/353 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs1031311197; called by muse, mutect2, varscan2
- CELSR1 | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 57/465 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs752335721; called by muse, varscan2
- CELSR2 | c.8623C>T p.R2875W | Missense Mutation (SNP) | VAF 46/367 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.756); catalogued as rs372843147; called by muse, mutect2, varscan2
- CELSR3 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 71/470 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV50842912; called by muse, mutect2, varscan2
- CEP44 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 45/393 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs377122523; called by muse, mutect2, varscan2
- CGAS | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149902826, COSV100943685; called by muse, mutect2, varscan2
- CHAF1B | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 60/438 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as rs372352704; called by muse, mutect2, varscan2
- CHCHD6 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs775129494; called by muse, mutect2, varscan2
- CHD5 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 60/438 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as rs866020323, COSV52412320; called by muse, mutect2, varscan2
- CHD6 | c.6575G>A p.R2192Q | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as rs200410567, COSV100950841; called by muse, mutect2, varscan2
- CHD7 | c.4885C>T p.R1629C | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs745837768, COSV101418015; called by muse, mutect2, varscan2
- CHPF | c.1924A>G p.M642V | Missense Mutation (SNP) | VAF 62/428 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs747618406; called by muse, mutect2, varscan2
- CHRDL2 | c.82+1G>A p.X28_splice | Splice Site (SNP) | VAF 39/318 reads (12%) | catalogued as rs1390735747; called by muse, mutect2, varscan2
- CIC | c.4790del p.P1597Hfs*23 | Frame Shift Del (DEL) | VAF 32/206 reads (16%) | catalogued as rs1158987717, COSV50583567; called by mutect2, pindel
- CLCNKA | c.1742T>C p.L581P | Missense Mutation (SNP) | VAF 51/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs779603150; called by muse, mutect2, varscan2
- CLGN | c.1622del p.K541Sfs*27 | Frame Shift Del (DEL) | VAF 52/348 reads (15%) | catalogued as rs1364341002; called by mutect2, varscan2
- CLIC4 | c.612del p.K204Nfs*11 | Frame Shift Del (DEL) | VAF 32/251 reads (13%) | catalogued as rs1175213607; called by mutect2, pindel, varscan2
- CMKLR1 | c.304G>T p.D102Y (on ENST00000312143 / NM_001142344.2; = p.D100Y on NM_004072.3) | Missense Mutation (SNP) | VAF 52/392 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs1190751376; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CNGB1 | c.3062C>T p.T1021M | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs774186674, COSV51898360; called by muse, mutect2, varscan2
- COL12A1 | c.4924del p.E1642Sfs*5 | Frame Shift Del (DEL) | VAF 42/316 reads (13%) | catalogued as COSV59390565; called by mutect2, pindel, varscan2
- COL7A1 | c.4096C>T p.R1366W | Missense Mutation (SNP) | VAF 53/410 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs147089666, CM137501; called by muse, mutect2, varscan2
- COL7A1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 43/439 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755047832, COSV60398734; called by muse, mutect2, varscan2
- COL9A2 | c.1371C>T p.G457= | Splice Region (SNP) | VAF 18/527 reads (3%) | catalogued as rs1244724713; called by muse, mutect2
- CRB1 | c.3064A>C p.S1022R | Missense Mutation (SNP) | VAF 53/363 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV66328752; called by muse, mutect2, varscan2
- CROCC2 | c.4016del p.P1339Qfs*56 | Frame Shift Del (DEL) | VAF 73/469 reads (16%) | catalogued as rs1198302748; called by mutect2, pindel, varscan2
- CSPP1 | c.1562G>A p.R521H (on ENST00000676605; = p.R480H on NM_024790.6) | Missense Mutation (SNP) | VAF 40/494 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767353646, COSV99138564; called by muse, mutect2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 28/268 reads (10%) | catalogued as rs767756120; called by mutect2, varscan2
- CSTF3 | c.613del p.M205* | Frame Shift Del (DEL) | VAF 18/178 reads (10%) | catalogued as rs1300471016; called by mutect2, varscan2
- CTDP1 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 76/695 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs553366579; called by muse, mutect2, varscan2
- CTNND1 | c.2653C>T p.R885W | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs369783710; called by muse, mutect2, varscan2
- CTU1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 44/372 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1457266350; called by muse, mutect2, varscan2
- CYP26C1 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.228); catalogued as rs373243793; called by muse, mutect2, varscan2
- CYP2C9 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs768830601, COSV53247735; called by muse, mutect2, varscan2
- CYP2F1 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs201357530; called by muse, mutect2, varscan2
- CYP7B1 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs779597828; called by muse, mutect2, varscan2
- DBH | c.1763C>T p.T588I | Missense Mutation (SNP) | VAF 53/402 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV101256955; called by muse, mutect2, varscan2
- DCHS1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 55/441 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs762047221, COSV100202441; called by muse, mutect2, varscan2
- DDRGK1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs142914025; called by muse, mutect2, varscan2
- DDX21 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 46/418 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); catalogued as rs1007685653; called by muse, mutect2, varscan2
- DDX23 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 65/418 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.614); catalogued as rs371260357; called by muse, mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 28/152 reads (18%) | catalogued as rs772416332; called by mutect2, varscan2
- DEAF1 | c.1083A>G p.I361M | Missense Mutation (SNP) | VAF 54/396 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs914130541; called by muse, mutect2, varscan2
- DENND4A | c.3442C>T p.R1148C | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs374306473; called by muse, mutect2, varscan2
- DHODH | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs764110385, COSV54663896; called by muse, mutect2, varscan2
- DHX34 | c.1017G>A p.T339= | Splice Region (SNP) | VAF 29/248 reads (12%) | catalogued as rs368953997; called by muse, mutect2, varscan2
- DHX37 | c.2287C>T p.R763W | Missense Mutation (SNP) | VAF 47/319 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs770231743; called by muse, mutect2, varscan2
- DHX8 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 56/403 reads (14%) | catalogued as rs751521418, COSV52251003; called by muse, mutect2, varscan2
- DISP2 | c.4169G>A p.R1390H | Missense Mutation (SNP) | VAF 58/371 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs761767631; called by muse, mutect2, varscan2
- DLL1 | c.672G>A p.P224= | Splice Region (SNP) | VAF 49/404 reads (12%) | catalogued as rs1241568400; called by muse, mutect2, varscan2
- DMKN | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 38/312 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs757510350; called by muse, mutect2, varscan2
- DNAH11 | c.131A>C p.E44A | Missense Mutation (SNP) | VAF 86/617 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs750407994; called by muse, varscan2
- DNAH7 | c.5315C>T p.A1772V | Missense Mutation (SNP) | VAF 54/434 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs748432820, COSV100415893; called by muse, mutect2, varscan2
- DNAH7 | c.4804C>T p.R1602C | Missense Mutation (SNP) | VAF 41/369 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186636152; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 42/204 reads (21%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK5 | c.3488G>A p.R1163K | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs777002703; called by muse, mutect2, varscan2
- DOT1L | c.1516C>A p.Q506K | Missense Mutation (SNP) | VAF 35/329 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV67107923; called by muse, mutect2, varscan2
- DST | c.4496del p.L1499Wfs*8 (on ENST00000361203 / NM_001374722.1; = p.L1173Wfs*8 on NM_015548.5) | Frame Shift Del (DEL) | VAF 39/297 reads (13%) | catalogued as rs35805169; called by mutect2, pindel, varscan2
- DUOX1 | c.1753C>A p.R585S | Missense Mutation (SNP) | VAF 62/507 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV58477147; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 30/212 reads (14%) | catalogued as rs746928635; called by mutect2, varscan2
- DUSP5 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1411766291; called by muse, mutect2, varscan2
- E2F7 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754738203, COSV59738194; called by muse, mutect2, varscan2
- ECEL1 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 65/414 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1184780729; called by muse, mutect2, varscan2
- EDA2R | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs746281957, COSV53632434; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 72/487 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs548003465; called by muse, mutect2, varscan2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 25/241 reads (10%) | catalogued as rs745309220; called by mutect2, varscan2
- EHF | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776494379, COSV57668635; called by muse, mutect2, varscan2
- EID3 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 62/445 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.756); catalogued as rs1482549757; called by muse, mutect2, varscan2
- EIF3A | c.3440G>A p.R1147H | Missense Mutation (SNP) | VAF 81/439 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs1340768719, COSV64961271; called by muse, mutect2, varscan2
- EIF3L | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 70/447 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as rs751635601; called by muse, mutect2, varscan2
- EN1 | c.171del p.S58Rfs*54 | Frame Shift Del (DEL) | VAF 34/262 reads (13%) | catalogued as rs1363146947; called by pindel, varscan2
- ENKUR | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 44/356 reads (12%) | catalogued as rs759631743, COSV100482256; called by muse, varscan2
- ENO1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 47/463 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.917); catalogued as rs761970983; called by muse, mutect2, varscan2
- ENO4 | c.1828C>T p.P610S (on ENST00000622726; = p.P607S on NM_001242699.2) | Missense Mutation (SNP) | VAF 56/442 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.068); catalogued as rs1234163410; called by muse, mutect2, varscan2
- EPHA5 | c.2404G>A p.A802T | Missense Mutation (SNP) | VAF 44/412 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56671245, COSV99895975; called by muse, mutect2, varscan2
- EPN2 | c.1483del p.L495* | Frame Shift Del (DEL) | VAF 46/384 reads (12%) | catalogued as COSV59060133; called by mutect2, pindel, varscan2
- EPOR | c.1506del p.S503Afs*13 | Frame Shift Del (DEL) | VAF 47/364 reads (13%) | catalogued as rs752862659; called by mutect2, pindel, varscan2
- ERBB4 | c.1916C>T p.T639M | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs532377012, COSV53542123; called by muse, mutect2, varscan2
- ERICH4 | c.64del p.Q22Rfs*3 | Frame Shift Del (DEL) | VAF 59/420 reads (14%) | catalogued as rs567420399; called by mutect2, pindel, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 66/414 reads (16%) | catalogued as rs775950025; called by mutect2, varscan2
- ESRRB | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 56/459 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs991653082, COSV55058930; called by muse, mutect2, varscan2
- EVPL | c.4900C>T p.R1634W | Missense Mutation (SNP) | VAF 59/475 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.332); catalogued as rs756132170, COSV56913872; called by muse, mutect2, varscan2
- EXOC1 | c.2457G>T p.K819N | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV62121981; called by muse, mutect2
- EXT1 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 38/344 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as rs138855109; called by muse, mutect2, varscan2
- F2RL2 | c.988T>A p.Y330N | Missense Mutation (SNP) | VAF 45/393 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs969191202, COSV56971589, COSV56972269; called by muse, mutect2, varscan2
- FAAP100 | c.2629A>G p.S877G | Missense Mutation (SNP) | VAF 65/475 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as rs775580833; called by muse, mutect2, varscan2
- FAHD2A | c.842dup p.G282Rfs*17 | Frame Shift Ins (INS) | VAF 60/401 reads (15%) | catalogued as rs766589051; called by mutect2, varscan2
- FAM193B | c.219dup p.A74Rfs*34 | Frame Shift Ins (INS) | VAF 34/275 reads (12%) | catalogued as rs765995572; called by mutect2, varscan2
- FAM222B | c.635A>G p.Q212R | Missense Mutation (SNP) | VAF 69/448 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.217); catalogued as rs1449041759; called by muse, mutect2, varscan2
- FAM71E1 | c.137del p.P46Lfs*19 | Frame Shift Del (DEL) | VAF 65/506 reads (13%) | catalogued as COSV58542475; called by mutect2, pindel, varscan2
- FAT4 | c.6737G>A p.S2246N | Missense Mutation (SNP) | VAF 46/378 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1304629534; called by muse, mutect2, varscan2
- FBLN1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774940379; called by muse, mutect2
- FBN3 | c.8303C>T p.P2768L | Missense Mutation (SNP) | VAF 82/521 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs143984778; called by muse, mutect2, varscan2
- FBN3 | c.7415G>A p.C2472Y | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374133420; called by muse, mutect2, varscan2
- FBN3 | c.4102G>A p.E1368K | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as rs150421324; called by muse, mutect2
- FBRSL1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 70/720 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as rs1263791338; called by muse, mutect2
- FCSK | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 50/463 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs755892030; called by muse, mutect2, varscan2
- FER1L6 | c.2308G>A p.G770S | Missense Mutation (SNP) | VAF 47/352 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1367789193; called by muse, mutect2, varscan2
- FGFR2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 61/459 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as rs1354205157, COSV100337040; called by muse, mutect2, varscan2
- FIGNL2 | c.1093del p.E365Rfs*14 | Frame Shift Del (DEL) | VAF 44/408 reads (11%) | catalogued as rs1361047104; called by mutect2, pindel
- FNDC1 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 51/508 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1283200757, COSV51933577; called by muse, mutect2, varscan2
- FNDC4 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 48/436 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs753394525, COSV53021001; called by muse, mutect2, varscan2
- FOLH1 | c.1501del p.S501Vfs*12 | Frame Shift Del (DEL) | VAF 31/293 reads (11%) | catalogued as rs764290022, COSV57049642; called by mutect2, pindel, varscan2
- FOXB2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 42/358 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769898531; called by muse, mutect2, varscan2
- FOXG1 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 57/425 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM124697; called by muse, mutect2, varscan2
- FOXRED1 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 37/328 reads (11%) | catalogued as rs758408106; called by muse, mutect2
- FRAS1 | c.11711C>T p.A3904V | Missense Mutation (SNP) | VAF 61/445 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as rs750578354, COSV53594701; called by muse, mutect2, varscan2
- FRYL | c.7481C>T p.A2494V | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs752057204, COSV99977821; called by muse, mutect2, varscan2
- FRYL | c.6385A>G p.I2129V | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1346004504; called by muse, mutect2
- FSCN3 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs148605578; called by muse, mutect2, varscan2
- FSTL5 | c.366dup p.Q123Tfs*9 | Frame Shift Ins (INS) | VAF 29/285 reads (10%) | catalogued as rs1293605811; called by mutect2, pindel, varscan2
- FZD9 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 63/445 reads (14%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.479); catalogued as rs782237874, COSV60670830; called by muse, mutect2, varscan2
- GABBR1 | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 125/482 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63542359; called by muse, mutect2, varscan2
- GABRP | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 34/335 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs772816775; called by muse, mutect2, varscan2
- GIMAP8 | c.1950G>A p.M650I | Missense Mutation (SNP) | VAF 45/391 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs897340459; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 30/186 reads (16%) | catalogued as rs750227570; called by mutect2, varscan2
- GJC2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.992); catalogued as COSV100813007; called by muse, mutect2, varscan2
- GLB1L | c.1270A>G p.I424V | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1439956898; called by muse, mutect2, varscan2
- GNAL | c.593G>A p.R198Q (on ENST00000269162 / NM_001142339.3; = p.R275Q on NM_182978.4) | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs1209224135; called by muse, mutect2, varscan2
- GNL2 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769914689, COSV56169955; called by muse, varscan2
- GNL2 | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 33/257 reads (13%) | catalogued as rs766601741; called by muse, varscan2
- GPD2 | c.1621A>G p.I541V | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60090777; called by muse, mutect2, varscan2
- GPHB5 | c.225dup p.Y76Lfs*3 | Frame Shift Ins (INS) | VAF 30/306 reads (10%) | catalogued as rs1566639983; called by mutect2, pindel
- GPR148 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 59/441 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs764014596, COSV59308831; called by muse, mutect2, varscan2
- GPR173 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 71/299 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as rs1489379691; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 56/375 reads (15%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR27 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99816550; called by muse, mutect2, varscan2
- GRAMD1B | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 52/387 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772035485, COSV59200080; called by muse, mutect2, varscan2
- GRHPR | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs370733771; called by muse, mutect2, varscan2
- GRIN2A | c.4021del p.S1341Afs*56 | Frame Shift Del (DEL) | VAF 52/393 reads (13%) | catalogued as COSV58051797; called by mutect2, pindel, varscan2
- GRIN2B | c.3338C>T p.P1113L | Missense Mutation (SNP) | VAF 57/456 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as rs766946947, COSV74205993; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2C | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 65/473 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as rs1366750564; called by muse, mutect2, varscan2
- GRIP1 | c.1762A>G p.I588V (on ENST00000359742 / NM_001379345.1; = p.I536V on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs368870661; called by muse, mutect2, varscan2
- GRN | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 48/331 reads (15%) | catalogued as rs1277918638; called by muse, mutect2, varscan2
- GSX1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 51/409 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57232800; called by muse, mutect2, varscan2
- GUCY2C | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as rs549407455; called by muse, mutect2, varscan2
- GUCY2D | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 73/541 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs761828482; called by muse, mutect2, varscan2
- HAS1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 59/392 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs769147211, COSV55787758; called by muse, mutect2, varscan2
- HASPIN | c.379A>G p.S127G | Missense Mutation (SNP) | VAF 59/469 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.587); catalogued as rs1405403700; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 49/290 reads (17%) | catalogued as rs746547303; called by mutect2, varscan2
- HCK | c.9del p.R4_?3 | Frame Shift Del (DEL) | VAF 50/365 reads (14%) | catalogued as rs755024531; called by mutect2, pindel, varscan2
- HDGFL1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 56/410 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1053977643, COSV57752119, COSV57753015; called by muse, varscan2
- HMGCLL1 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 49/331 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762734248; called by muse, mutect2, varscan2
- HOXD8 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.135); catalogued as rs1400279572; called by muse, varscan2
- HPS6 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 60/465 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1164116927; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 46/286 reads (16%) | catalogued as rs748579647; called by mutect2, varscan2
- HTR3C | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 61/475 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs771861231, COSV100570616, COSV59176715; called by muse, mutect2, varscan2
- IFT57 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 51/452 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1395771768; called by muse, mutect2, varscan2
- IGDCC4 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as rs546982667; called by muse, mutect2, varscan2
- IGF2R | c.2618C>T p.S873L | Missense Mutation (SNP) | VAF 53/388 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs199514599; called by muse, mutect2, varscan2
- IGLV3-32 | c.299A>G p.E100G | Missense Mutation (SNP) | VAF 67/400 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746723728; called by muse, mutect2, varscan2
- IL1F10 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 55/442 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs140754412; called by muse, mutect2, varscan2
- IL1RAP | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 52/434 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs763802602, COSV50759217; called by muse, mutect2, varscan2
- INA | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1177406922, COSV100878607; called by muse, mutect2, varscan2
- INPP5D | c.3244C>T p.R1082W (on ENST00000445964 / NM_001017915.3; = p.R1081W on NM_005541.5) | Missense Mutation (SNP) | VAF 64/529 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1474478891; called by muse, mutect2, varscan2
- INPP5K | c.578T>C p.M193T | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs1290409250; called by muse, mutect2, varscan2
- INSRR | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 56/414 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV104427273; called by muse, mutect2, varscan2
- INSRR | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 41/328 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100947178; called by muse, mutect2, varscan2
- IPO7 | c.2786A>G p.D929G | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as rs763654555; called by muse, mutect2, varscan2
- IRX5 | c.805dup p.R269Pfs*187 | Frame Shift Ins (INS) | VAF 44/269 reads (16%) | catalogued as rs754238323; called by mutect2, varscan2
- ITFG1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs766871022, COSV57744631, COSV57751781; called by muse, mutect2, varscan2
- ITFG2 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1223824337; called by muse, mutect2, varscan2
- ITGB4 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1191842048, COSV52322406; called by muse, mutect2, varscan2
- ITGB6 | c.329T>A p.I110N | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs371257499; called by muse, mutect2, varscan2
- ITPRID2 | c.2716_2718del p.P906del | In Frame Del (DEL) | VAF 48/436 reads (11%) | catalogued as rs752793925; called by pindel, varscan2
- IWS1 | c.1745del p.K582Sfs*4 | Frame Shift Del (DEL) | VAF 45/260 reads (17%) | catalogued as rs1558747232; called by mutect2, pindel, varscan2
- JADE1 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1282462259, COSV56908510, COSV56909510; called by muse, mutect2, varscan2
- JRK | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 61/463 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs587669418; called by muse, mutect2, varscan2
- KALRN | c.2855C>T p.T952M | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs532130353, COSV53774491; called by muse, mutect2, varscan2
- KAT14 | c.488dup p.L163Ffs*5 | Frame Shift Ins (INS) | VAF 23/259 reads (9%) | catalogued as rs1480801806; called by mutect2, pindel
- KAT2B | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.25); catalogued as rs1413665077; called by muse, mutect2, varscan2
- KCNA3 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 45/424 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63902122; called by muse, mutect2, varscan2
- KCNA6 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99768200; called by muse, mutect2, varscan2
- KCND2 | c.13del p.V5Wfs*41 | Frame Shift Del (DEL) | VAF 25/280 reads (9%) | catalogued as COSV58583583, COSV58589056; called by mutect2, varscan2
- KCNG1 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.132); catalogued as rs1044410528; called by muse, mutect2, varscan2
- KCNH5 | c.2836del p.S946Afs*77 | Frame Shift Del (DEL) | VAF 42/449 reads (9%) | catalogued as COSV59756030; called by mutect2, pindel, varscan2
- KCNQ1 | c.1643G>A p.G548D | Missense Mutation (SNP) | VAF 65/393 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199472799, CM057175; ClinVar: not provided; called by muse, mutect2, varscan2
- KDF1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57670792; called by muse, varscan2
- KDM2B | c.3118C>T p.R1040C | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1555288565; called by muse, mutect2, varscan2
- KIAA1109 | c.12640C>T p.R4214W | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52665577; called by muse, varscan2
- KIAA1549L | c.2212C>A p.L738M (on ENST00000321505; = p.L1035M on NM_012194.3) | Missense Mutation (SNP) | VAF 58/443 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.253); catalogued as rs377476148; called by muse, mutect2, varscan2
- KIAA1614 | c.2689G>A p.V897I | Missense Mutation (SNP) | VAF 59/460 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs766645484, COSV62550473; called by muse, mutect2, varscan2
- KIF7 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 51/347 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs780615343; called by muse, mutect2, varscan2
- KIRREL2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.685); catalogued as rs939777968, COSV52874329; called by muse, mutect2, varscan2
- KISS1R | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 71/405 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs1445430129; called by muse, mutect2, varscan2
- KLHL30 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 64/432 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs764966810; called by muse, mutect2, varscan2
- KLHL38 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 65/544 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs375307692; called by muse, mutect2, varscan2
- KMT2D | c.15520C>T p.R5174W | Missense Mutation (SNP) | VAF 45/424 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56432925; called by muse, mutect2, varscan2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 34/168 reads (20%) | catalogued as rs761148574; called by mutect2, varscan2
- KRT20 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 75/541 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.108); catalogued as rs1427410174; called by muse, mutect2, varscan2
- KRT33B | c.72del p.S25Afs*17 | Frame Shift Del (DEL) | VAF 70/606 reads (12%) | catalogued as rs752320759; called by pindel, varscan2
- KRT9 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs780497214, COSV55851649; called by muse, mutect2, varscan2
- LAMA5 | c.9101del p.G3034Afs*73 | Frame Shift Del (DEL) | VAF 38/394 reads (10%) | catalogued as rs780673654; called by mutect2, pindel, varscan2
- LARP1 | c.2708G>A p.R903H (on ENST00000518297 / NM_033551.3; = p.R826H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV60427143; called by muse, mutect2, varscan2
- LDHAL6A | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs796971912; called by muse, mutect2, varscan2
- LDLR | c.2026G>A p.G676S | Missense Mutation (SNP) | VAF 54/406 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745753810, CM024122, CM066909, CM162061; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LIMCH1 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149800400, COSV58292524; called by muse, mutect2, varscan2
- LIMK1 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 62/402 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs781932129; called by muse, mutect2, varscan2
- LINGO2 | c.565T>G p.L189V | Missense Mutation (SNP) | VAF 42/468 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58061713; called by muse, mutect2
- LIX1L | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 59/355 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370597290; called by muse, mutect2, varscan2
- LMBRD2 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs752249915; called by muse, mutect2
- LMO4 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 37/323 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as rs532279574, COSV65170501; called by muse, mutect2, varscan2
- LONRF2 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs751549783, COSV104433064; called by muse, mutect2, varscan2
- LPO | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV99031655; called by muse, mutect2, varscan2
- LRFN1 | c.1600G>A p.G534S | Missense Mutation (SNP) | VAF 63/445 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1311669138; called by muse, mutect2, varscan2
- LRFN3 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 51/442 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1346581668, COSV55817866; called by muse, mutect2, varscan2
- LRP1 | c.6617G>A p.R2206H | Missense Mutation (SNP) | VAF 62/428 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1371377915, COSV54503511, COSV54514106; called by muse, mutect2, varscan2
- LRP1B | c.13699A>G p.M4567V | Missense Mutation (SNP) | VAF 53/373 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1481931689; called by muse, mutect2, varscan2
- LRPPRC | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 47/395 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.949); catalogued as rs879004882, COSV53243841; called by muse, mutect2, varscan2
- LRRC17 | c.1272dup p.H425Tfs*2 | Frame Shift Ins (INS) | VAF 50/411 reads (12%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC7 | c.556G>A p.A186T (on ENST00000651989 / NM_001370785.2; = p.A153T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs766366739, COSV99226080; called by muse, mutect2, varscan2
- LRRN1 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 64/397 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs773309234, COSV60014720; called by muse, mutect2, varscan2
- LRRTM3 | c.1375C>T p.R459* | Nonsense Mutation (SNP) | VAF 63/388 reads (16%) | catalogued as COSV63670942; called by muse, mutect2, varscan2
- LRRTM4 | c.1244A>G p.Q415R | Missense Mutation (SNP) | VAF 55/486 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as rs1267008188; called by muse, mutect2, varscan2
- LSMEM2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 45/349 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs374858403; called by muse, mutect2, varscan2
- LTBP3 | c.330G>A p.V110= | Splice Region (SNP) | VAF 35/258 reads (14%) | catalogued as rs1458468458; called by muse, mutect2, varscan2
- MAB21L4 | c.1081C>T p.R361C (on ENST00000388934 / NM_001085437.3; = p.R193C on NM_024861.4) | Missense Mutation (SNP) | VAF 55/477 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs747929041; called by muse, mutect2, varscan2
- MACF1 | c.14956C>T p.R4986W (on ENST00000372915; = p.R2919W on NM_012090.5) | Missense Mutation (SNP) | VAF 57/416 reads (14%) | catalogued as rs766474090; called by muse, mutect2, varscan2
- MAP11 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as rs776902372; called by muse, mutect2, varscan2
- MAP3K13 | c.1457T>C p.L486S | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1326887263; called by muse, mutect2, varscan2
- MAP3K3 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs761104061; called by muse, mutect2, varscan2
- MAP7D1 | c.2219G>A p.G740D | Missense Mutation (SNP) | VAF 45/406 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1057268296, COSV60218522; called by muse, mutect2, varscan2
- MAPK9 | c.491C>A p.T164N | Missense Mutation (SNP) | VAF 46/393 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs756962280, COSV58121483; called by muse, mutect2, varscan2
- MARCKS | c.803A>G p.K268R | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.303); catalogued as rs1429642481; called by muse, mutect2, varscan2
- MAS1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 44/364 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs753527518, COSV53120830; called by muse, mutect2, varscan2
- MATN2 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as rs1007833956; called by muse, mutect2, varscan2
- MATN4 | c.1535G>A p.R512H (on ENST00000372754; = p.R471H on NM_003833.4) | Missense Mutation (SNP) | VAF 40/306 reads (13%) | PolyPhen probably damaging (0.976); catalogued as rs778280289, COSV61352191; called by muse, mutect2, varscan2
- MBOAT7 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 58/481 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs202020450, COSV55478522; called by muse, mutect2, varscan2
- MC1R | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 39/395 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748521098; called by muse, mutect2, varscan2
- MEDAG | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs1221416232; called by muse, mutect2, varscan2
- MEGF8 | c.4289C>T p.A1430V (on ENST00000251268 / NM_001271938.2; = p.A1363V on NM_001410.3) | Missense Mutation (SNP) | VAF 76/491 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs777183202, COSV52088566; called by muse, mutect2, varscan2
- MEPCE | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 58/516 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1473273452; called by muse, mutect2, varscan2
- MEX3B | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 84/502 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as COSV61664435; called by muse, mutect2, varscan2
- MGA | c.4562T>C p.F1521S | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1014755173; called by muse, mutect2, varscan2
- MIDN | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 33/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748137724; called by muse, mutect2, varscan2
- MIGA2 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.084); catalogued as rs1368453480, COSV52977321; called by muse, mutect2, varscan2
- MIS18BP1 | c.695del p.L232Wfs*3 | Frame Shift Del (DEL) | VAF 36/264 reads (14%) | catalogued as rs1284538816; called by mutect2, pindel, varscan2
- MMP16 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 53/460 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs760497058, COSV54161518, COSV99688817; called by muse, mutect2, varscan2
- MMP24 | c.1714_1716del p.K572del | In Frame Del (DEL) | VAF 61/501 reads (12%) | catalogued as rs757961147; called by mutect2, pindel, varscan2
- MMP25 | c.1235del p.P412Rfs*43 | Frame Shift Del (DEL) | VAF 57/464 reads (12%) | catalogued as COSV60679335; called by mutect2, pindel, varscan2
- MPO | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 67/497 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs1282170793; called by muse, mutect2, varscan2
- MRNIP | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 43/373 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs1279911726; called by muse, mutect2
- MROH5 | c.241A>G p.M81V | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs1005634703; called by muse, mutect2
- MRPL39 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as rs1383562052, COSV100221114; called by muse, mutect2, varscan2
- MS4A14 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as rs146613208; called by muse, mutect2, varscan2
- MTCL1 | c.1808G>A p.R603Q (on ENST00000306329 / NM_001378206.1; = p.R243Q on NM_015210.4) | Missense Mutation (SNP) | VAF 54/492 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs199899364, COSV60406815; called by muse, mutect2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 24/174 reads (14%) | catalogued as rs759847587; called by mutect2, varscan2
- MTHFSD | c.994G>A p.V332M (on ENST00000360900 / NM_001159377.2; = p.V331M on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/465 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as rs376801434; called by muse, mutect2, varscan2
- MTMR14 | c.1856G>A p.R619Q (on ENST00000296003 / NM_001077525.3; = p.R507Q on NM_022485.5) | Missense Mutation (SNP) | VAF 73/467 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs765867569; called by muse, mutect2, varscan2
- MTRR | c.1276C>T p.R426C (on ENST00000264668; = p.R399C on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531325011, COSV52947015; called by muse, varscan2
- MUC17 | c.10070C>T p.A3357V | Missense Mutation (SNP) | VAF 58/417 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs567258117; called by muse, mutect2, varscan2
- MUC4 | c.14440G>A p.A4814T (on ENST00000463781 / NM_018406.7; = p.A578T on NM_004532.6) | Missense Mutation (SNP) | VAF 82/580 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.803); catalogued as rs1350628582; called by muse, mutect2
- MUC4 | c.4460C>T p.T1487M | Missense Mutation (SNP) | VAF 32/557 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs201808250; called by muse, mutect2
- MUSK | c.691C>A p.L231M | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51885040; called by muse, mutect2, varscan2
- MYH10 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 30/299 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs757539505, COSV52610538; called by muse, mutect2, varscan2
- MYH9 | c.4078G>A p.A1360T | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs569649580, COSV53393946; called by muse, mutect2, varscan2
- MYO19 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1381642926; called by muse, mutect2, varscan2
- MYO1B | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 42/339 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs760053053, COSV58427070; called by muse, mutect2, varscan2
- MYO1E | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178412708, COSV99896840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO5A | c.4712A>G p.Y1571C | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100698212; called by muse, varscan2
- MYO5B | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.284); catalogued as rs758821508, COSV53222506; called by muse, mutect2, varscan2
- MYO9A | c.6733G>A p.V2245M | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.293); catalogued as rs1475467337; called by muse, mutect2, varscan2
- MYO9A | c.5153G>A p.R1718Q | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.767); catalogued as rs968502392, COSV61848564; called by muse, mutect2, varscan2
- MYO9B | c.4015C>T p.R1339W | Missense Mutation (SNP) | VAF 66/431 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs748214669; called by muse, mutect2, varscan2
- MZT2A | c.440del p.G147Afs*? | Frame Shift Del (DEL) | VAF 72/457 reads (16%) | catalogued as rs753638030; called by mutect2, pindel, varscan2
- NAA25 | c.1710del p.H571Tfs*33 | Frame Shift Del (DEL) | VAF 40/301 reads (13%) | catalogued as COSV55710118; called by pindel, varscan2
- NAP1L2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.043); catalogued as rs759636463, COSV65172305; called by muse, mutect2, varscan2
- NAP1L3 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV59077988; called by muse, varscan2
- NARS1 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs370597508; called by muse, mutect2, varscan2
- NAT14 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 46/412 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1312512120; called by mutect2, varscan2
- NCAPD3 | c.2725dup p.Q909Pfs*12 | Frame Shift Ins (INS) | VAF 36/328 reads (11%) | catalogued as rs770284236; called by mutect2, varscan2
- NCOA5 | c.1010del p.G337Afs*38 | Frame Shift Del (DEL) | VAF 56/504 reads (11%) | catalogued as rs1200193975; called by mutect2, pindel, varscan2
- NEB | c.17639C>T p.T5880I | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as rs780269152; called by muse, mutect2, varscan2
- NEU3 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 62/486 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs749465509, COSV53637774; called by muse, mutect2, varscan2
- NF1 | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.57); catalogued as rs1422095982; called by muse, mutect2
- NFASC | c.808G>A p.A270T (on ENST00000339876 / NM_001378329.1; = p.A281T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs371635013, COSV58370618; called by muse, mutect2, varscan2
- NFATC1 | c.2092+6G>A | Splice Region (SNP) | VAF 48/347 reads (14%) | catalogued as rs753194409, COSV53695979; called by muse, mutect2, varscan2
- NFATC2 | c.2218G>A p.A740T | Missense Mutation (SNP) | VAF 54/427 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs758439316, COSV101043847; called by muse, mutect2, varscan2
- NFE2L1 | c.2122C>T p.R708* | Nonsense Mutation (SNP) | VAF 63/502 reads (13%) | catalogued as COSV62582686; called by muse, mutect2, varscan2
- NFKB2 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs200373995; called by muse, mutect2, varscan2
- NINJ1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 59/417 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs145421928; called by muse, mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 79/420 reads (19%) | catalogued as rs763440516; called by mutect2, varscan2
- NKX6-3 | c.778C>A p.L260M (on ENST00000518699 / NM_001364841.2; = p.L130M on NM_152568.3) | Missense Mutation (SNP) | VAF 55/369 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs957347546; called by muse, mutect2, varscan2
- NLRX1 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 62/486 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.082); catalogued as rs1375367613; called by muse, mutect2, varscan2
- NOBOX | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 44/346 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as rs780611966, COSV56193927; called by muse, mutect2, varscan2
- NOL6 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 61/410 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747103900; called by muse, mutect2, varscan2
- NOP53 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 77/552 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as rs769427571; called by muse, mutect2, varscan2
- NPTX1 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 67/370 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as COSV60777044; called by muse, mutect2, varscan2
- NRXN2 | c.3175C>T p.R1059W | Missense Mutation (SNP) | VAF 55/446 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200881363, COSV55454740; called by muse, mutect2, varscan2
- NSD2 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 49/439 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.096); catalogued as rs150146753; called by muse, mutect2, varscan2
- NTN1 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 20/410 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as rs940885304; called by muse, mutect2
- NUFIP2 | c.670del p.R224Gfs*16 | Frame Shift Del (DEL) | VAF 66/472 reads (14%) | catalogued as rs772197760; called by mutect2, pindel, varscan2
- NUP155 | c.512T>C p.V171A (on ENST00000231498 / NM_153485.3; = p.V112A on NM_004298.4) | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV51535495; called by muse, mutect2, varscan2
- NUP62 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 70/417 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs758695990, COSV61313680; called by muse, mutect2, varscan2
- NUP98 | c.1207A>G p.T403A | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as rs745577949; called by muse, mutect2, varscan2
- NUTM2G | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 51/391 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as rs1378740588; called by muse, mutect2, varscan2
- NXF3 | c.722C>A p.S241* | Nonsense Mutation (SNP) | VAF 63/221 reads (29%) | catalogued as COSV67705049; called by muse, mutect2, varscan2
- OAT | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs370970194; called by muse, mutect2, varscan2
- OBSCN | c.1996C>A p.H666N | Missense Mutation (SNP) | VAF 53/455 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1322029851; called by muse, mutect2, varscan2
- OLAH | c.419G>A p.R140H (on ENST00000378228 / NM_001039702.3; = p.R193H on NM_018324.3) | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as rs145059634; called by muse, mutect2, varscan2
- OMD | c.1142G>T p.R381M | Missense Mutation (SNP) | VAF 52/375 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV100978998; called by muse, mutect2, varscan2
- OPA3 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs186796646, COSV54398876, COSV54398945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OPCML | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV100104052; called by muse, mutect2, varscan2
- OPLAH | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 49/378 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200773486, COSV101470702; ClinVar: uncertain significance; called by muse, varscan2
- OPLAH | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 58/485 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782203973; called by muse, mutect2, varscan2
- OR2V2 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 51/345 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.26); catalogued as rs745838099; called by muse, mutect2, varscan2
- OR4C15 | c.346T>A p.L116M (on ENST00000314644; = p.L62M on NM_001001920.2) | Missense Mutation (SNP) | VAF 63/435 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58952394, COSV58952408, COSV58954071; called by muse, mutect2, varscan2
- OR5AR1 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV57253554; called by muse, mutect2, varscan2
- OR5W2 | c.39del p.L14Sfs*10 | Frame Shift Del (DEL) | VAF 47/330 reads (14%) | catalogued as rs772083907; called by mutect2, pindel, varscan2
- OR6N2 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59413188; called by muse, mutect2, varscan2
- OR8J1 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 68/529 reads (13%) | catalogued as rs374279068, COSV57317963; called by muse, mutect2, varscan2
- OTOG | c.8548C>T p.R2850C | Missense Mutation (SNP) | VAF 57/418 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1189461532; called by muse, mutect2, varscan2
- OTUD7A | c.1498G>T p.G500C (on ENST00000307050 / NM_001382637.1; = p.G493C on NM_130901.3) | Missense Mutation (SNP) | VAF 23/579 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV61035747; called by muse, mutect2
- P3H2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1380005051; called by muse, varscan2
- PANK4 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 60/544 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs749136554; called by muse, mutect2, varscan2
- PAPLN | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs761483973; called by muse, mutect2, varscan2
- PAPPA2 | c.4036T>G p.S1346A | Missense Mutation (SNP) | VAF 57/496 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV62811476; called by muse, mutect2, varscan2
- PAPSS1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs867093052, COSV54494072; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 34/336 reads (10%) | catalogued as CM011452; called by pindel, varscan2
- PCDH18 | c.215dup p.N73Kfs*11 | Frame Shift Ins (INS) | VAF 58/477 reads (12%) | catalogued as COSV100786927; called by mutect2, pindel, varscan2
- PCDHA9 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 76/529 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.533); catalogued as rs1562447443, COSV99061574; called by muse, mutect2, varscan2
- PCDHB2 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 26/664 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99165985; called by muse, mutect2
- PCF11 | c.1400_1401del p.Q467Rfs*10 | Frame Shift Del (DEL) | VAF 54/430 reads (13%) | catalogued as rs1432552369, COSV53534586; called by mutect2, pindel, varscan2
- PCLO | c.14376G>T p.W4792C | Missense Mutation (SNP) | VAF 53/294 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61651450; called by muse, mutect2, varscan2
- PCNT | c.8711C>T p.A2904V | Missense Mutation (SNP) | VAF 48/389 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV64026800; called by muse, mutect2, varscan2
- PCNX2 | c.1856del p.K619Rfs*52 | Frame Shift Del (DEL) | VAF 54/314 reads (17%) | catalogued as COSV50784264; called by mutect2, pindel, varscan2
- PDCL | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 59/416 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs756766356, COSV52342054; called by muse, mutect2, varscan2
- PDE1C | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58507644; called by muse, mutect2
- PDE4A | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); catalogued as COSV61797677; called by muse, mutect2, varscan2
- PDE8B | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.934); catalogued as rs747059922, COSV53732486, COSV53733876; called by muse, mutect2, varscan2
- PDLIM2 | c.1022G>A p.R341H (on ENST00000397760; = p.R591H on NM_021630.6) | Missense Mutation (SNP) | VAF 42/411 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1048363031; called by muse, mutect2, varscan2
- PDZD7 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 50/428 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as rs201804536; called by muse, mutect2, varscan2
- PEG3 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 71/466 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs762568322, COSV55629902; called by muse, mutect2, varscan2
- PEX1 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 53/382 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs374010060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEX14 | c.952_954del p.E318del | In Frame Del (DEL) | VAF 65/500 reads (13%) | catalogued as rs1557442698; called by pindel, varscan2
- PEX6 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201265954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 42/290 reads (14%) | catalogued as rs769717544; called by mutect2, varscan2
- PIEZO2 | c.6988G>A p.V2330I | Missense Mutation (SNP) | VAF 45/292 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as rs756549202, COSV53286661; called by muse, mutect2, varscan2
- PIF1 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 46/297 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as rs141053049; called by muse, mutect2, varscan2
- PIK3R1 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs143572224; called by muse, mutect2, varscan2
- PKHD1 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs564240823, COSV61859047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLA2G3 | c.1388A>G p.Q463R | Missense Mutation (SNP) | VAF 41/408 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV53211412; called by muse, mutect2, varscan2
- PLAA | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101263528; called by muse, mutect2, varscan2
- PLAT | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 52/442 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1415478927; called by muse, mutect2, varscan2
- PLCB3 | c.833del p.K278Sfs*38 | Frame Shift Del (DEL) | VAF 55/366 reads (15%) | catalogued as COSV54188895; called by pindel, varscan2
- PLEKHM2 | c.2689C>T p.R897C | Missense Mutation (SNP) | VAF 56/456 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs375841573; called by muse, mutect2, varscan2
- PLK1 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as rs745801697, COSV55622017; called by muse, mutect2, varscan2
- PLPPR4 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 56/378 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as rs776227807; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 59/445 reads (13%) | catalogued as rs953293505; called by mutect2, pindel, varscan2
- POLR2A | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 52/407 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as rs150809300, COSV100495764; called by muse, mutect2, varscan2
- POLR2B | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58901889; called by muse, mutect2, varscan2
- POM121L12 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 61/462 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.328); catalogued as rs756931097; called by muse, mutect2, varscan2
- POMGNT2 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 43/416 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1194187476; called by muse, mutect2, varscan2
- PPP4R3C | c.2111T>C p.M704T | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs868077248; called by muse, mutect2, varscan2
- PRDM10 | c.2477C>T p.T826M | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs771230126; called by muse, varscan2
- PRDM13 | c.1767G>T p.K589N | Missense Mutation (SNP) | VAF 75/420 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65028900; called by muse, mutect2, varscan2
- PRDM2 | c.196del p.R66Dfs*37 | Frame Shift Del (DEL) | VAF 28/233 reads (12%) | catalogued as rs112778466; called by pindel, varscan2
- PRDM9 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 54/437 reads (12%) | catalogued as COSV99690943; called by muse, mutect2, varscan2
- PRKCG | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 40/321 reads (12%) | catalogued as rs929413725, COSV54733790; called by muse, mutect2, varscan2
- PRPF19 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 50/355 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as rs1349076964; called by muse, mutect2, varscan2
- PRR23A | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as rs1420782431; called by muse, mutect2, varscan2
- PSMA8 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs769332898, COSV57601172; called by muse, mutect2, varscan2
- PTPN6 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs782599498, COSV100016826, COSV100016895; called by muse, mutect2, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 55/445 reads (12%) | catalogued as rs772722517, COSV99560265; called by pindel, varscan2
- PZP | c.3473A>G p.Y1158C | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776471406; called by muse, mutect2, varscan2
- RAB44 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 114/391 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs909371481; called by muse, mutect2, varscan2
- RAB6A | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60180616; called by muse, mutect2, varscan2
- RAD9A | c.1002del p.K335Rfs*62 | Frame Shift Del (DEL) | VAF 48/343 reads (14%) | catalogued as rs756633055; called by mutect2, pindel, varscan2
- RADIL | c.1286del p.G429Afs*6 | Frame Shift Del (DEL) | VAF 63/454 reads (14%) | catalogued as rs768989877; called by mutect2, pindel, varscan2
- RALGAPA2 | c.2754del p.S919Afs*24 | Frame Shift Del (DEL) | VAF 37/376 reads (10%) | catalogued as COSV99173620; called by mutect2, pindel, varscan2
- RAPGEF4 | c.2149G>A p.G717R | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as rs774211535; called by muse, mutect2, varscan2
- RASAL1 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs199548072, COSV55657711; called by muse, mutect2, varscan2
- RBM20 | c.128A>C p.Q43P | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as rs886046698; ClinVar: uncertain significance; called by mutect2, varscan2
- RBM4 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 37/412 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs752990000, COSV59518509; called by muse, mutect2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 38/290 reads (13%) | catalogued as COSV56484832; called by mutect2, varscan2
- RCC2 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 51/340 reads (15%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.009); catalogued as rs1190956143; called by muse, mutect2, varscan2
- RECQL4 | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 79/667 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs190061994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELB | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 62/407 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as rs376021184; called by muse, varscan2
- RGL4 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs371757094; called by muse, mutect2
- RGS19 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 42/406 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760857132; called by muse, mutect2, varscan2
- RGSL1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 50/434 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1208223371, COSV54256694; called by muse, mutect2, varscan2
- RHOT2 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs769839120; called by muse, varscan2
- RHPN1 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 53/453 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs754083890; called by muse, mutect2, varscan2
- RIC1 | c.2576A>G p.H859R | Missense Mutation (SNP) | VAF 39/389 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99317058; called by muse, mutect2, varscan2
- RMDN3 | c.1156del p.T386Lfs*22 | Frame Shift Del (DEL) | VAF 36/284 reads (13%) | catalogued as rs745408248; called by mutect2, varscan2
- RNF213 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 74/466 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs777537902; called by muse, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 57/430 reads (13%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF44 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs756584401; called by muse, mutect2, varscan2
- RNPEPL1 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 47/350 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773622869, COSV54373245; called by muse, mutect2, varscan2
- ROR2 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs369545969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RP1 | c.458del p.P153Hfs*4 | Frame Shift Del (DEL) | VAF 51/541 reads (9%) | catalogued as rs781249059; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 42/310 reads (14%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA1 | c.1104del p.S369Afs*18 | Frame Shift Del (DEL) | VAF 36/228 reads (16%) | catalogued as rs745561139; called by mutect2, varscan2
- RSKR | c.803A>G p.Q268R | Missense Mutation (SNP) | VAF 42/413 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs752535339; called by muse, mutect2, varscan2
- RTN4 | c.1421G>A p.S474N | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV104398304; called by muse, mutect2, varscan2
- RUSC1 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 62/444 reads (14%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); catalogued as rs747878710; called by muse, mutect2, varscan2
- S100A5 | c.273_275del p.N91del | In Frame Del (DEL) | VAF 40/232 reads (17%) | catalogued as rs752535190; called by pindel, varscan2
- SALL1 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 48/386 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51757133; called by muse, mutect2, varscan2
- SALL3 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 79/610 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1425501004; called by muse, mutect2, varscan2
- SAMD7 | c.213T>C p.G71= | Splice Region (SNP) | VAF 26/327 reads (8%) | catalogued as COSV59418026; called by muse, mutect2
- SASH1 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs768183967, COSV100820990; called by muse, mutect2, varscan2
- SCAMP1 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 37/364 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs750255612; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 22/250 reads (9%) | catalogued as rs765136101; called by mutect2, pindel
- SCN2A | c.2786del p.F929Sfs*5 | Frame Shift Del (DEL) | VAF 55/422 reads (13%) | catalogued as COSV51838952; called by mutect2, pindel, varscan2
- SDK2 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as rs1567774779; called by muse, mutect2, varscan2
- SEC16A | c.2048C>T p.T683M | Missense Mutation (SNP) | VAF 61/421 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs376288098; called by muse, mutect2, varscan2
- SEC24D | c.2461C>T p.R821W | Missense Mutation (SNP) | VAF 32/351 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771020078; called by muse, mutect2
- SERGEF | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1202027594; called by muse, mutect2, varscan2
- SFT2D3 | c.242_248del p.G81Afs*11 | Frame Shift Del (DEL) | VAF 52/392 reads (13%) | catalogued as rs748029693; called by mutect2, pindel, varscan2
- SHTN1 | c.1415A>G p.N472S | Missense Mutation (SNP) | VAF 40/321 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as COSV53386674; called by muse, mutect2, varscan2
- SIGLEC8 | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 54/404 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs745778438; called by muse, mutect2, varscan2
- SIK2 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as rs1238557118; called by muse, mutect2, varscan2
- SIK3 | c.3724C>T p.R1242C (on ENST00000445177 / NM_001366686.2; = p.R1200C on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/403 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs747877301, COSV52608877, COSV52623220; called by muse, mutect2, varscan2
- SIK3 | c.2789C>T p.A930V (on ENST00000445177 / NM_001366686.2; = p.A888V on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.007); catalogued as COSV99408609; called by muse, mutect2, varscan2
- SIPA1L2 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs760944168, COSV53400181; called by muse, mutect2, varscan2
- SIRT2 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs751291175; called by muse, mutect2
- SLC15A3 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 64/456 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs1285507025; called by muse, varscan2
- SLC1A6 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 41/422 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1301909733, COSV99694151; called by muse, mutect2, varscan2
- SLC22A18 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs371786058; called by muse, mutect2, varscan2
- SLC25A22 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 64/408 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs574361397; called by muse, mutect2, varscan2
- SLC25A42 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs546562344; called by muse, mutect2, varscan2
- SLC35F1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 66/419 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs759991380; called by muse, mutect2, varscan2
- SLC39A3 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 43/361 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs781612783, COSV99514135; called by muse, mutect2, varscan2
- SLC45A4 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 56/484 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs1182257743; called by muse, mutect2, varscan2
- SLC5A10 | c.1267G>A p.V423M (on ENST00000395645 / NM_001042450.4; = p.V439M on NM_152351.5) | Missense Mutation (SNP) | VAF 61/340 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs200567946; called by muse, mutect2, varscan2
- SLC7A2 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs748996480, COSV50250396; called by muse, varscan2
- SLC9A5 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs368066325; called by muse, varscan2
- SLC9B2 | c.242A>G p.H81R | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs200766604; called by muse, mutect2, varscan2
- SLC9C2 | c.1130G>T p.W377L | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV62946730; called by muse, mutect2, varscan2
- SLCO6A1 | c.1625dup p.M543Dfs*9 | Frame Shift Ins (INS) | VAF 16/124 reads (13%) | catalogued as rs866444182; called by mutect2, varscan2
- SLIT3 | c.3640C>T p.R1214W | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs548039062; called by muse, mutect2, varscan2
- SMARCA4 | c.3325A>G p.M1109V | Missense Mutation (SNP) | VAF 57/445 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV60808410; called by muse, mutect2, varscan2
- SMARCA5 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 49/359 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs764115299, COSV51644542; called by muse, mutect2, varscan2
- SMARCC2 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV99911344; called by muse, mutect2, varscan2
- SNAPC3 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs758031602; called by muse, mutect2, varscan2
- SNUPN | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373228145; called by muse, varscan2
- SOBP | c.1271G>T p.S424I | Missense Mutation (SNP) | VAF 64/457 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57995185; called by muse, mutect2, varscan2
- SOGA3 | c.890del p.P297Lfs*77 | Frame Shift Del (DEL) | VAF 58/444 reads (13%) | catalogued as rs765347158; called by mutect2, pindel, varscan2
- SORBS3 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368264093; called by muse, varscan2
- SORCS3 | c.1346C>A p.A449E | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63830620; called by muse, mutect2
- SOST | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 80/458 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs756754655, COSV100059602; called by muse, mutect2, varscan2
- SOX6 | c.2117G>A p.R706Q (on ENST00000528429 / NM_001145819.2; = p.R679Q on NM_017508.3) | Missense Mutation (SNP) | VAF 49/385 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57045542; called by muse, mutect2, varscan2
- SPACA9 | c.451T>C p.W151R | Missense Mutation (SNP) | VAF 50/453 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs748327621; called by muse, mutect2, varscan2
- SPAG1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 33/499 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.427); catalogued as rs1060503106, COSV52562815; ClinVar: uncertain significance; called by muse, mutect2
- SPAG11A | c.281del p.F94Sfs*43 (on ENST00000642566; = p.F94Sfs*63 on NM_001081552.3) | Frame Shift Del (DEL) | VAF 29/179 reads (16%) | catalogued as rs754013498, COSV58500193; called by mutect2, varscan2
- SPAG7 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs369733828; called by muse, mutect2, varscan2
- SPRR2F | c.187T>C p.C63R | Missense Mutation (SNP) | VAF 60/525 reads (11%) | PolyPhen possibly damaging (0.625); catalogued as COSV100907507; called by muse, mutect2, varscan2
- SPTBN1 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 55/449 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as rs780467374; called by muse, mutect2, varscan2
- SPTBN1 | c.5606G>A p.R1869H | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as rs779220012, COSV100443158; called by muse, mutect2, varscan2
- SRCAP | c.8306A>G p.Q2769R | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.901); catalogued as rs1488695792, COSV52670054; called by muse, mutect2
- SREK1IP1 | c.381del p.K129Nfs*29 | Frame Shift Del (DEL) | VAF 30/228 reads (13%) | catalogued as rs1470980144, COSV72486131; called by mutect2, pindel, varscan2
- STAMBP | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754485280, COSV59897336; called by muse, mutect2, varscan2
- SUGCT | c.1206del p.L403Cfs*10 (on ENST00000335693 / NM_001193313.2; = p.L429Cfs*10 on NM_024728.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/375 reads (9%) | catalogued as rs745753530, COSV59316072; called by mutect2, pindel, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 34/255 reads (13%) | catalogued as rs753462162; called by mutect2, varscan2
- SYK | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs139348511; called by muse, mutect2, varscan2
- SYNE1 | c.14355G>T p.K4785N (on ENST00000367255 / NM_182961.4; = p.K4714N on NM_033071.3) | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as rs751898330; called by muse, mutect2, varscan2
- SYNJ2 | c.3685C>T p.R1229C | Missense Mutation (SNP) | VAF 70/439 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1156811180, COSV100840154; called by muse, mutect2, varscan2
- TAF1C | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 61/386 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.371); catalogued as rs746955225; called by muse, varscan2
- TAF4 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as rs1007683356; called by muse, mutect2, varscan2
- TAF5L | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 47/463 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753094205; called by muse, mutect2, varscan2
- TAL1 | c.185del p.G62Afs*13 | Frame Shift Del (DEL) | VAF 45/374 reads (12%) | catalogued as rs1289673879; called by mutect2, pindel, varscan2
- TAL1 | c.86dup p.H30Afs*146 | Frame Shift Ins (INS) | VAF 56/364 reads (15%) | catalogued as rs750167290; called by mutect2, varscan2
- TBC1D4 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); catalogued as rs373660487; called by muse, mutect2, varscan2
- TCF3 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 65/508 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs372168347; called by muse, mutect2, varscan2
- TCN1 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 29/326 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs147187383; called by muse, mutect2
- TDRD1 | c.2059G>A p.V687M | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs143109750; called by muse, mutect2, varscan2
- TECTA | c.3259G>A p.G1087S | Missense Mutation (SNP) | VAF 49/403 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs748368038; called by muse, mutect2, varscan2
- TENM4 | c.6731G>A p.R2244H | Missense Mutation (SNP) | VAF 52/414 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1193250974, COSV104376879; called by muse, mutect2, varscan2
- TERF1 | c.1244G>A p.R415Q (on ENST00000276603 / NM_017489.3; = p.R395Q on NM_003218.4) | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749879752, COSV99401232; called by muse, mutect2
- TFPI | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as rs137865208, COSV104373397; called by muse, mutect2, varscan2
- THYN1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs777723936, COSV55539637; called by muse, mutect2, varscan2
- TJP2 | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 81/538 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771756670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TJP2 | c.3062C>T p.A1021V | Missense Mutation (SNP) | VAF 45/437 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99601265; called by muse, mutect2, varscan2
- TKFC | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs368722603; called by muse, mutect2, varscan2
- TLN1 | c.6986G>A p.R2329Q | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs768328246; called by muse, mutect2, varscan2
- TM4SF4 | c.36del p.T13Pfs*23 | Frame Shift Del (DEL) | VAF 52/373 reads (14%) | catalogued as rs747355584; called by mutect2, pindel, varscan2
- TMA16 | c.45del p.V16Sfs*25 | Frame Shift Del (DEL) | VAF 33/314 reads (11%) | catalogued as rs570113265, COSV62187391; called by mutect2, varscan2
- TMEM161B | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs746854349, COSV56930339; called by muse, mutect2, varscan2
- TMEM225 | c.374A>C p.K125T | Missense Mutation (SNP) | VAF 33/373 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100902729; called by muse, mutect2
- TMEM63B | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 50/441 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs781648674; called by muse, mutect2, varscan2
- TMEM82 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 48/415 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.459); catalogued as rs375870524; called by muse, mutect2, varscan2
- TMEM94 | c.657del p.F220Sfs*31 | Frame Shift Del (DEL) | VAF 63/509 reads (12%) | catalogued as rs753764149; called by mutect2, pindel, varscan2
- TNFRSF6B | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 54/445 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV53928034; called by muse, mutect2, varscan2
- TNN | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 67/489 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV53421489; called by muse, mutect2, varscan2
- TNNI3 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 50/367 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as rs1408482066; called by muse, mutect2, varscan2
- TNRC6C | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 61/414 reads (15%) | catalogued as rs753191295; called by muse, mutect2, varscan2
- TOP3A | c.2524A>G p.S842G | Missense Mutation (SNP) | VAF 62/459 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV58176476; called by muse, mutect2, varscan2
- TOP3A | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 37/238 reads (16%) | catalogued as rs1432573544; called by muse, mutect2, varscan2
- TOPORS | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 47/409 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs748479572, COSV104418008; called by muse, mutect2, varscan2
- TRAF1 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 24/395 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs560261396, COSV100875219; called by muse, mutect2
- TRAF3IP3 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 59/437 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs751484314, COSV50550407; called by muse, mutect2, varscan2
- TRAV2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1276145626; called by muse, mutect2, varscan2
- TRIM32 | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 50/441 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV100528625; called by muse, mutect2, varscan2
- TRIM71 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 48/319 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1208997935, COSV67471183; called by muse, mutect2, varscan2
- TRIOBP | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 91/687 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs753164237, COSV60375082; called by muse, mutect2
- TRIOBP | c.6392G>A p.R2131Q (on ENST00000644935 / NM_001039141.3; = p.R418Q on NM_007032.5) | Missense Mutation (SNP) | VAF 64/453 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs764196291; called by muse, mutect2, varscan2
- TRIR | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs747584062; called by muse, mutect2, varscan2
- TRO | c.1428A>C p.Q476H | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51508772; called by muse, mutect2, varscan2
- TRUB1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs781079988; called by muse, mutect2, varscan2
- TRUB1 | c.595dup p.L199Pfs*20 | Frame Shift Ins (INS) | VAF 30/184 reads (16%) | catalogued as rs762997509; called by mutect2, varscan2
- TSHZ1 | c.3050T>C p.V1017A (on ENST00000580243 / NM_001308210.2; = p.V972A on NM_005786.6) | Missense Mutation (SNP) | VAF 18/445 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100433276; called by muse, mutect2
- TSNAXIP1 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 59/379 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs141527864; called by muse, mutect2, varscan2
- TTC28 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 42/347 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1467718469; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 51/288 reads (18%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTN | c.63320del p.P21107Hfs*15 (on ENST00000591111; = p.P13683Hfs*15 on NM_003319.4) | Frame Shift Del (DEL) | VAF 38/318 reads (12%) | catalogued as COSV100603882; called by mutect2, pindel, varscan2
- TTN | c.58241C>T p.P19414L (on ENST00000591111; = p.P11990L on NM_003319.4) | Missense Mutation (SNP) | VAF 41/323 reads (13%) | PolyPhen possibly damaging (0.759); catalogued as rs779343098, COSV100615548, COSV60011249; called by muse, mutect2, varscan2
- TTN | c.52585G>A p.G17529R (on ENST00000591111; = p.G10105R on NM_003319.4) | Missense Mutation (SNP) | VAF 47/292 reads (16%) | PolyPhen probably damaging (1); catalogued as rs750947988, COSV104415690; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- TUBGCP6 | c.5426G>A p.R1809H | Missense Mutation (SNP) | VAF 50/357 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs540957245, COSV99955171; called by muse, mutect2, varscan2
- TUBGCP6 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs533130736, COSV50587289; called by muse, mutect2, varscan2
- TYSND1 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 52/394 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs564621500; called by muse, mutect2, varscan2
- ULK3 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215517316; called by muse, mutect2, varscan2
- UNC13A | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 54/354 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV53193672; called by muse, mutect2, varscan2
- UNC13C | c.4004A>C p.K1335T | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.337); catalogued as COSV52845640, COSV99512011; called by muse, mutect2, varscan2
- UNC13D | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs763117746; called by muse, mutect2, varscan2
- UNC5B | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 66/450 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746870907, COSV58974351; called by muse, mutect2, varscan2
- UPF2 | c.3099A>T p.E1033D | Missense Mutation (SNP) | VAF 67/402 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1367060563, COSV62658267; called by muse, mutect2, varscan2
- URB1 | c.5534C>T p.A1845V | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as rs571515712, COSV104430270; called by muse, mutect2, varscan2
- USP36 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs759332450; called by muse, mutect2, varscan2
- USP49 | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 31/245 reads (13%) | catalogued as rs987984442; called by muse, mutect2, varscan2
- USPL1 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as rs767643992; called by muse, mutect2, varscan2
- UTP4 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 64/602 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58733957; called by muse, mutect2, varscan2
- UTRN | c.6970G>A p.V2324I | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs757500422; called by muse, varscan2
- VARS2 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 116/477 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs758010983, COSV52557692; called by muse, mutect2, varscan2
- VPS13C | c.10403G>T p.G3468V (on ENST00000644861 / NM_020821.3; = p.G3425V on NM_017684.5) | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1233791284; called by muse, mutect2, varscan2
- VPS37C | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745353366; called by muse, mutect2, varscan2
- VPS50 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs747891799, COSV52492228; called by muse, mutect2, varscan2
- VSIG8 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 53/472 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs780079437; called by muse, mutect2, varscan2
- VSX1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 49/494 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs1367189291; called by muse, mutect2, varscan2
- WASHC4 | c.1584del p.K528Nfs*13 | Frame Shift Del (DEL) | VAF 39/339 reads (12%) | catalogued as COSV59889719; called by mutect2, pindel, varscan2
- XDH | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 47/352 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs151251011; called by muse, mutect2, varscan2
- XKR6 | c.1705G>A p.G569R | Missense Mutation (SNP) | VAF 46/416 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.08); catalogued as COSV58655950; called by muse, mutect2, varscan2
- XPO6 | c.390del p.F130Lfs*7 | Frame Shift Del (DEL) | VAF 37/289 reads (13%) | catalogued as COSV100485170; called by mutect2, pindel, varscan2
- YTHDF1 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 54/463 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.797); catalogued as rs756585496; called by muse, mutect2, varscan2
- ZBED6CL | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 45/432 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs143446716; called by muse, mutect2, varscan2
- ZBTB10 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 29/288 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as rs1191358843; called by muse, varscan2
- ZBTB20 | c.1667C>T p.A556V (on ENST00000474710 / NM_001164342.2; = p.A483V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/423 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1323958910, COSV61862518; called by muse, mutect2, varscan2
- ZC2HC1B | c.516del p.E173Nfs*29 | Frame Shift Del (DEL) | VAF 36/300 reads (12%) | catalogued as rs1562343162; called by mutect2, pindel, varscan2
- ZC3H18 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 20/427 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1233259804; called by muse, mutect2
- ZDHHC11B | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 33/447 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs760720870; called by muse, mutect2
- ZEB2 | c.924del p.K308Nfs*30 | Frame Shift Del (DEL) | VAF 65/482 reads (13%) | catalogued as CD012279; called by mutect2, pindel, varscan2
- ZFHX4 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 54/482 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.103); catalogued as rs923379132, COSV50678515; called by muse, mutect2, varscan2
- ZFYVE1 | c.2232C>A p.F744L | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.361); catalogued as COSV100606829; called by muse, mutect2, varscan2
- ZFYVE26 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 50/373 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); catalogued as rs1361696412; called by muse, mutect2, varscan2
- ZIM3 | c.1318del p.T440Pfs*98 | Frame Shift Del (DEL) | VAF 39/425 reads (9%) | catalogued as rs760126796, COSV99517559, COSV99518191, COSV99518981; called by mutect2, pindel
- ZMYM4 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as rs188028902; called by muse, mutect2, varscan2
- ZNF160 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 54/372 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs187006418, COSV62000286; called by muse, mutect2, varscan2
- ZNF2 | c.1214C>T p.T405M (on ENST00000611147 / NM_001291605.2; = p.T392M on NM_021088.4) | Missense Mutation (SNP) | VAF 58/435 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745767414, COSV54637027; called by muse, mutect2, varscan2
- ZNF337 | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 40/458 reads (9%) | catalogued as rs369850723; called by muse, mutect2
- ZNF426 | c.438_439del p.C146* | Nonsense Mutation (DEL) | VAF 46/351 reads (13%) | catalogued as rs1296723987; called by pindel, varscan2
- ZNF440 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 51/366 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV58371633; called by muse, mutect2
- ZNF503 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 40/376 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99055689; called by muse, mutect2, varscan2
- ZNF512B | c.2644C>T p.R882W | Missense Mutation (SNP) | VAF 53/466 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as rs200897348; called by muse, mutect2, varscan2
- ZNF513 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 64/484 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1375856507, COSV52009696; called by muse, mutect2, varscan2
- ZNF552 | c.915del p.F305Lfs*119 | Frame Shift Del (DEL) | VAF 55/467 reads (12%) | catalogued as rs774574605; called by mutect2, pindel, varscan2
- ZNF563 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 52/519 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201449606; called by muse, mutect2
- ZNF582 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 58/430 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs759782368, COSV56731258; called by muse, mutect2, varscan2
- ZNF626 | c.659A>C p.K220T | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV74130101; called by muse, mutect2, varscan2
- ZNF644 | c.3970G>A p.E1324K (on ENST00000337393 / NM_201269.3; = p.E102K on NM_016620.3) | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs771685544; called by muse, mutect2, varscan2
- ZNF83 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 53/425 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as rs762225164, COSV99991334; called by muse, mutect2, varscan2
- ZPLD1 | c.1167_1169del p.L390del (on ENST00000466937 / NM_001329788.1; = p.L406del on NM_175056.2) | In Frame Del (DEL) | VAF 40/352 reads (11%) | catalogued as rs1280615575; called by pindel, varscan2
- ZSCAN2 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 68/476 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs146985684; called by muse, mutect2, varscan2
- ZXDC | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 27/320 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs1455849669, COSV60448347; called by muse, mutect2
- A2ML1 | c.4201C>T p.L1401F | Missense Mutation (SNP) | VAF 42/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- AADACL4 | c.224del p.L75Yfs*5 | Frame Shift Del (DEL) | VAF 49/361 reads (14%) | called by mutect2, pindel, varscan2
- AASDH | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 56/339 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABTB1 | c.753del p.E252Sfs*102 (on ENST00000232744 / NM_172027.3; = p.E110Sfs*102 on NM_032548.3) | Frame Shift Del (DEL) | VAF 35/244 reads (14%) | called by mutect2, pindel, varscan2
- AC008397.2 | c.1351T>C p.Y451H | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AC025287.4 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- AC068580.4 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AC127029.3 | c.756del p.R253Gfs*88 | Frame Shift Del (DEL) | VAF 46/394 reads (12%) | called by mutect2, varscan2
- ACACB | c.4207C>A p.R1403S | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ACBD3 | c.1281dup p.G428Wfs*7 | Frame Shift Ins (INS) | VAF 61/488 reads (13%) | called by mutect2, pindel, varscan2
- ACIN1 | c.3533C>T p.S1178L | Missense Mutation (SNP) | VAF 58/392 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACSS3 | c.489T>A p.H163Q | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS17 | c.1871C>T p.T624I | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ADAMTS18 | c.2741G>T p.S914I | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ADAMTS3 | c.971A>C p.N324T | Missense Mutation (SNP) | VAF 43/369 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ADAMTS5 | c.733_734del p.S245Afs*31 | Frame Shift Del (DEL) | VAF 65/525 reads (12%) | called by pindel, varscan2
- ADCY4 | c.3197T>C p.L1066S | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRB1 | c.802T>C p.S268P | Missense Mutation (SNP) | VAF 35/443 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2
- ADIG | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- AFF2 | c.2101G>A p.G701S | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AGAP6 | c.949G>T p.V317F (on ENST00000374056 / NM_001365867.1; = p.V340F on NM_001077665.2) | Missense Mutation (SNP) | VAF 63/531 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AGBL1 | c.1622del p.P541Lfs*33 | Frame Shift Del (DEL) | VAF 45/428 reads (11%) | called by mutect2, pindel, varscan2
- AKIRIN2 | c.414del p.E139Nfs*12 | Frame Shift Del (DEL) | VAF 32/353 reads (9%) | called by mutect2, pindel
- AKR1B15 | c.201A>C p.E67D | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, varscan2
- ALG8 | c.792A>C p.Q264H | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALOX12B | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 63/452 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- AMH | c.381del p.Q128Sfs*11 | Frame Shift Del (DEL) | VAF 55/402 reads (14%) | called by mutect2, pindel, varscan2
- AMOTL2 | c.40C>A p.R14S | Missense Mutation (SNP) | VAF 52/434 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- AMPD1 | c.2125A>G p.T709A | Missense Mutation (SNP) | VAF 44/379 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- ANKRA2 | c.923T>A p.L308H | Missense Mutation (SNP) | VAF 42/295 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ANKRD11 | c.6532G>A p.D2178N | Missense Mutation (SNP) | VAF 54/427 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD17 | c.152_154del p.P51del | In Frame Del (DEL) | VAF 46/390 reads (12%) | called by pindel, varscan2
- ANKRD30A | c.381T>A p.D127E (on ENST00000611781; = p.D71E on NM_052997.2) | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ANKRD34A | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 62/485 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ANKRD46 | c.580A>G p.R194G | Missense Mutation (SNP) | VAF 51/523 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); called by muse, mutect2
- ANLN | c.341G>T p.S114I | Missense Mutation (SNP) | VAF 66/434 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ANO4 | c.2834A>G p.K945R (on ENST00000392977 / NM_001286615.2; = p.K910R on NM_178826.4) | Missense Mutation (SNP) | VAF 47/406 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- APOBR | c.2011G>A p.G671R (on ENST00000431282; = p.G680R on NM_018690.4) | Missense Mutation (SNP) | VAF 60/459 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AQP3 | c.691T>A p.W231R | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARAP1 | c.3415T>A p.F1139I (on ENST00000393609 / NM_001040118.2; = p.F894I on NM_015242.4) | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARFGEF1 | c.3566A>G p.E1189G | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.179); called by muse, mutect2
- ARHGAP19 | c.135del p.F45Lfs*35 | Frame Shift Del (DEL) | VAF 58/377 reads (15%) | called by mutect2, pindel, varscan2
- ARHGAP31 | c.3995del p.G1332Vfs*16 | Frame Shift Del (DEL) | VAF 46/327 reads (14%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.3496A>T p.I1166F (on ENST00000310343 / NM_001378025.1; = p.I817F on NM_014715.4) | Missense Mutation (SNP) | VAF 56/430 reads (13%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP4 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 65/291 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF28 | c.1050del p.K350Nfs*18 | Frame Shift Del (DEL) | VAF 30/264 reads (11%) | called by mutect2, varscan2
- ARPC2 | c.131A>G p.H44R | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- ARRB1 | c.1085A>G p.H362R | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARSI | c.1122G>A p.W374* | Nonsense Mutation (SNP) | VAF 45/411 reads (11%) | called by muse, mutect2, varscan2
- ATP1A3 | c.2947A>G p.M983V (on ENST00000545399 / NM_001256214.2; = p.M970V on NM_152296.5) | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ATP2A2 | c.956T>G p.L319R | Missense Mutation (SNP) | VAF 48/417 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATXN1L | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.07); called by muse, mutect2
- BAG5 | c.561C>G p.N187K | Missense Mutation (SNP) | VAF 54/384 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- BAHCC1 | c.2662dup p.H888Pfs*186 | Frame Shift Ins (INS) | VAF 32/282 reads (11%) | called by mutect2, pindel, varscan2
- BCAT1 | c.263T>C p.L88S | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- BCDIN3D | c.505T>C p.W169R | Missense Mutation (SNP) | VAF 48/391 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BCOR | c.3344C>A p.P1115H | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- BDNF | c.339C>A p.Y113* | Nonsense Mutation (SNP) | VAF 57/370 reads (15%) | called by muse, mutect2, varscan2
- BEND2 | c.584A>G p.H195R | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP1 | c.139T>A p.C47S | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- BNIPL | c.720-3_738delinsAGGTATATGGTGGGAACTC p.X240_splice | Splice Site (DEL) | VAF 47/328 reads (14%) | called by pindel, varscan2*
- BPNT2 | c.176del p.G59Afs*23 | Frame Shift Del (DEL) | VAF 57/486 reads (12%) | called by mutect2, pindel, varscan2
- BRCA2 | c.5321C>A p.P1774Q | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- BTBD7 | c.1318del p.Y440Mfs*28 | Frame Shift Del (DEL) | VAF 56/446 reads (13%) | called by mutect2, pindel, varscan2
- C11orf24 | c.485T>C p.M162T | Missense Mutation (SNP) | VAF 77/522 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1QL2 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 57/468 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- C5AR1 | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 59/423 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- C9orf57 | c.185A>C p.K62T (on ENST00000377024 / NM_001371610.1; = p.K40T on NM_001128618.2) | Missense Mutation (SNP) | VAF 37/310 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen probably damaging (0.994); called by muse, mutect2
- CABIN1 | c.5501del p.G1834Afs*72 | Frame Shift Del (DEL) | VAF 61/453 reads (13%) | called by mutect2, pindel, varscan2
- CACNA1A | c.5996del p.P1999Rfs*25 | Frame Shift Del (DEL) | VAF 38/384 reads (10%) | called by mutect2, pindel
- CACNA2D1 | c.2176A>G p.I726V (on ENST00000356253 / NM_001366867.1; = p.I714V on NM_000722.4) | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CACNG7 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 54/450 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CADPS2 | c.3152C>T p.A1051V | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CALR | c.891del p.E298Sfs*52 | Frame Shift Del (DEL) | VAF 44/472 reads (9%) | called by mutect2, pindel
- CAMLG | c.639A>G p.I213M | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
1,024 further variants in this file (563 protein-altering or splice-affecting, 385 silent, 76 other) are not listed here.
